Somatic mutation profile of tumor specimen TCGA-KR-A7K2-01A (aliquot TCGA-KR-A7K2-01A-12D-A33Q-10) from TCGA case TCGA-KR-A7K2, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Combined hepatocellular carcinoma and cholangiocarcinoma; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 64.9 years (23,699 days).
Specimen TCGA-KR-A7K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f75af646-0867-47d5-b50c-e2fb7970e60a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KR-A7K2-10A (Blood Derived Normal), aliquot TCGA-KR-A7K2-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eced3758-857d-4913-a84e-39ce77309f6e

The open-access MAF lists 65 somatic variants for this specimen: 42 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 35, Silent 23, Frame Shift Del 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.857C>T p.S286L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV55598899; called by muse, mutect2, varscan2
- ADAM28 | c.119A>G p.H40R | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56106196; called by muse, mutect2, varscan2
- C6orf120 | c.367T>A p.S123T | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV59324611; called by muse, mutect2, varscan2
- CAPZA1 | c.728T>G p.I243S | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54147484; called by muse, mutect2, varscan2
- CATSPER2 | c.1531C>A p.R511S (on ENST00000321596 / NM_001282309.3; = p.R513S on NM_172095.4) | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148790135, COSV58662024; called by muse, mutect2, varscan2
- CDH18 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 51/100 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV56965170; called by muse, mutect2, varscan2
- CHD7 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as COSV71115078; called by muse, mutect2, varscan2
- CNGA3 | c.962A>G p.Y321C | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55628705; called by muse, mutect2, varscan2
- DENND1C | c.1090G>C p.A364P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.611); catalogued as COSV67375499; called by muse, mutect2, varscan2
- DMD | c.2962T>C p.S988P | Missense Mutation (SNP) | VAF 109/132 reads (83%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.649); catalogued as COSV63796891; called by muse, mutect2, varscan2
- ECT2L | c.50A>T p.K17M | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV62887505; called by muse, mutect2, varscan2
- FBN2 | c.1058C>T p.T353I | Missense Mutation (SNP) | VAF 100/252 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.041); catalogued as rs1204127908, COSV52547824; called by muse, mutect2, varscan2
- GABRG1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 83/296 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.906); catalogued as COSV54951561, COSV54962652; called by muse, mutect2, varscan2
- GPR149 | c.2056A>G p.N686D | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV67670554; called by muse, mutect2, varscan2
- GREB1 | c.2213A>G p.Y738C | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV52195058; called by muse, mutect2, varscan2
- GSN | c.501C>G p.Y167* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV58001967; called by muse, mutect2, varscan2
- INTS12 | c.1366G>T p.A456S | Missense Mutation (SNP) | VAF 56/104 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV60863026, COSV60863751; called by muse, mutect2, varscan2
- KDR | c.3944A>G p.D1315G | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.848); catalogued as COSV55777707; called by muse, mutect2, varscan2
- KRTAP9-2 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1414646945, COSV66647181; called by muse, mutect2, varscan2
- MDFIC | c.295G>C p.G99R | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs548881845, COSV57565046; called by muse, mutect2, varscan2
- MNT | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51514261; called by muse, mutect2, varscan2
- MORC3 | c.1490C>A p.S497* | Nonsense Mutation (SNP) | VAF 32/82 reads (39%) | catalogued as COSV68203749; called by muse, mutect2, varscan2
- NCDN | c.52A>T p.M18L | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV57851389; called by muse, mutect2, varscan2
- NOX4 | c.1523T>G p.I508S | Missense Mutation (SNP) | VAF 114/212 reads (54%) | SIFT tolerated (0.23); PolyPhen benign (0.065); catalogued as COSV54466004; called by muse, mutect2, varscan2
- NPC1L1 | c.3793T>A p.F1265I | Missense Mutation (SNP) | VAF 51/71 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56930949; called by muse, mutect2, varscan2
- PCLO | c.14604G>T p.Q4868H | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429413, COSV61671793; called by muse, mutect2, varscan2
- PLOD1 | c.1151A>C p.D384A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV52151038; called by muse, mutect2, varscan2
- PTBP1 | c.1178A>G p.H393R (on ENST00000349038 / NM_031991.4; = p.H419R on NM_002819.5) | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV62462002; called by muse, mutect2
- PTPRM | c.2215C>T p.H739Y | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV59883886; called by muse, mutect2, varscan2
- SGK1 | c.225_227del p.P77del | In Frame Del (DEL) | VAF 4/44 reads (9%) | catalogued as rs1210359128; called by pindel, varscan2
- TMEM71 | c.715C>G p.L239V (on ENST00000523829 / NM_001382398.1; = p.L220V on NM_144649.3) | Missense Mutation (SNP) | VAF 288/659 reads (44%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as COSV63459614, COSV63459694; called by muse, mutect2, varscan2
- TRIM43 | c.116T>A p.L39H | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1447401935, COSV99720101; called by muse, mutect2
- TYMP | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV52689586; called by muse, mutect2, varscan2
- VIL1 | c.2341C>T p.P781S | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV50299754; called by muse, mutect2, varscan2
- VPS13B | c.11558T>G p.V3853G | Missense Mutation (SNP) | VAF 68/326 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62159020; called by muse, mutect2, varscan2
- XIRP2 | c.9959G>T p.G3320V (on ENST00000628543; = p.G3495V on NM_152381.6) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54693377; called by muse, mutect2, varscan2
- ZC3H12B | c.1871G>A p.R624Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.143); catalogued as rs1486984540, COSV59049234, COSV59052182; called by muse, mutect2
- ZNF792 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 73/164 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV68694557; called by muse, mutect2, varscan2
- GBP5 | c.1729_1730del p.V577* | Frame Shift Del (DEL) | VAF 13/52 reads (25%) | called by mutect2, pindel, varscan2
- MSMO1 | c.373dup p.I125Nfs*4 | Frame Shift Ins (INS) | VAF 28/72 reads (39%) | called by mutect2, pindel, varscan2
- PODXL | c.1055_1062delinsT p.Q352Lfs*6 (on ENST00000378555 / NM_001018111.3; = p.Q320Lfs*6 on NM_005397.4) | Frame Shift Del (DEL) | VAF 36/161 reads (22%) | called by pindel, varscan2*
- TAF1B | c.399_399+14del p.X133_splice | Splice Site (DEL) | VAF 13/75 reads (17%) | called by mutect2, pindel, varscan2
- ABCC1 | c.1152C>T p.Y384= | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV60695273; called by muse, mutect2, varscan2
- APOB | c.10251C>A p.T3417= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV51955306; called by muse, mutect2, varscan2
- CSTF2 | c.969A>G p.G323= | Silent (SNP) | VAF 33/69 reads (48%) | catalogued as COSV65895287; called by muse, mutect2, varscan2
- FBF1 | c.2271C>T p.R757= (on ENST00000586717; = p.R771= on NM_001319193.1) | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs759210559, COSV59867339; called by muse, mutect2, varscan2
- FRMPD2 | c.717G>T p.T239= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV59724321; called by muse, mutect2, varscan2
- GJD4 | c.798G>A p.P266= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1175684732, COSV100397357; called by muse, mutect2
- GNPNAT1 | c.510T>C p.Y170= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV53592544; called by muse, mutect2
- GRK7 | c.303C>A p.T101= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV53825737; called by muse, mutect2, varscan2
- MLKL | c.1302T>G p.G434= | Silent (SNP) | VAF 48/118 reads (41%) | catalogued as COSV58206780; called by muse, mutect2, varscan2
- MYH15 | c.5103G>A p.R1701= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs760232088, COSV56321121; called by muse, mutect2, varscan2
- NFKB1 | c.1506A>G p.L502= (on ENST00000394820 / NM_001382627.1; = p.L503= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV56961446; called by muse, mutect2, varscan2
- PAPOLG | c.1221T>C p.N407= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV53186135; called by muse, mutect2
- PDS5A | c.1284A>G p.K428= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as COSV57832048; called by muse, mutect2, varscan2
- PRPF6 | c.2376G>A p.L792= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV53879586; called by muse, mutect2, varscan2
- PSCA | c.319C>T p.L107= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV56653788; called by muse, mutect2
- RREB1 | c.3105C>A p.L1035= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV58566605; called by muse, mutect2, varscan2
- RSPH10B2 | c.117G>A p.E39= | Silent (SNP) | VAF 20/188 reads (11%) | catalogued as COSV51871669; called by muse, mutect2
- RTL8C | c.273C>A p.L91= | Silent (SNP) | VAF 48/125 reads (38%) | catalogued as COSV57060788; called by muse, mutect2, varscan2
- RUVBL1 | c.330G>A p.E110= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV59477433; called by muse, mutect2, varscan2
- RYR2 | c.2691A>G p.K897= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV63718206; called by muse, mutect2, varscan2
- SLC39A12 | c.1665T>C p.D555= (on ENST00000377369 / NM_001145195.2; = p.D518= on NM_152725.3) | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as rs750412650, COSV66202879; called by muse, mutect2, varscan2
- SPHKAP | c.2964C>T p.S988= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs771825169, COSV60874764, COSV60877069; called by muse, mutect2, varscan2
- XPR1 | c.931T>C p.L311= | Silent (SNP) | VAF 16/107 reads (15%) | catalogued as COSV62560949; called by muse, mutect2, varscan2
